Somatic mutation profile of tumor specimen 0DPHT8 from CCDI case PBCDRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.1 years (2,959 days).
Specimen 0DPHT8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ff68a67-01e5-4757-96da-d98c07faa0b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPHT0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55fafb32-0cd5-4108-a4d4-fbf85c88173b

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 5'UTR 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRA1 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 166/376 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV66925906; called by muse, mutect2, varscan2
- C4orf54 | c.4898G>A p.R1633Q | Missense Mutation (SNP) | VAF 116/454 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs1339293634; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 22/325 reads (7%) | catalogued as rs754135731; called by mutect2, pindel*
- KNDC1 | c.4394C>T p.T1465M | Missense Mutation (SNP) | VAF 213/521 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as rs540301676, COSV58832829; called by muse, mutect2, varscan2
- MRC1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 268/847 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV58889914; called by muse, mutect2, varscan2
- OTOF | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 237/607 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs149701372; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2T33 | c.514A>T p.I172F | Missense Mutation (SNP) | VAF 25/986 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- PDZK1 | c.342G>C p.L114F | Missense Mutation (SNP) | VAF 183/531 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- TRIM40 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 236/442 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ADCY6 | c.780C>T p.A260= | Silent (SNP) | VAF 347/744 reads (47%) | catalogued as rs757694253; called by muse, mutect2, varscan2
- POGK | c.1596G>A p.A532= | Silent (SNP) | VAF 175/826 reads (21%) | catalogued as rs770826223, COSV63311745; called by muse, mutect2, varscan2
- UBASH3A | c.924G>A p.T308= | Silent (SNP) | VAF 395/907 reads (44%) | catalogued as rs144754371; called by muse, mutect2, varscan2
- GCKR | c.-8G>A | 5'UTR (SNP) | VAF 30/624 reads (5%) | catalogued as rs771102257; called by muse, mutect2
- SGSH | c.746-22G>A | Intron (SNP) | VAF 174/657 reads (26%) | called by muse, mutect2, varscan2
